Somatic mutation profile of tumor specimen TCGA-77-8136-01A (aliquot TCGA-77-8136-01A-11D-2244-08) from TCGA case TCGA-77-8136, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 74.5 years (27,193 days).
Specimen TCGA-77-8136-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f211c596-76c1-4600-9dc4-234efe3be19e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-77-8136-10A (Blood Derived Normal), aliquot TCGA-77-8136-10A-01D-2244-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bfc06958-a3db-4f8f-aec9-ff9daad47435

The open-access MAF lists 471 somatic variants for this specimen: 352 protein-altering or splice-affecting, 110 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 313, Silent 110, Nonsense Mutation 26, Splice Site 7, RNA 4, Intron 2, 5'UTR 2, Frame Shift Del 2, Splice Region 2, Frame Shift Ins 1, 5'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C3orf70 | c.17C>G p.S6W | Missense Mutation (SNP) | VAF 4/34 reads (12%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen benign (0.095); catalogued as rs757159118, COSV58586480, COSV58587413, COSV58588338; called by mutect2, varscan2
- PTEN | c.635-1G>C p.X212_splice | Splice Site (SNP) | VAF 25/128 reads (20%) | hotspot (GDC flag); catalogued as rs876661024, CS090867, CS993675, COSV64289221, COSV64292432, COSV64296169; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A4GNT | c.859C>A p.L287M | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99367888; called by muse, mutect2, varscan2
- AATK | c.3687G>C p.K1229N (on ENST00000326724 / NM_001080395.3; = p.K1126N on NM_004920.2) | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100352873; called by muse, mutect2, varscan2
- ACRBP | c.781C>G p.L261V | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV99976154; called by muse, mutect2, varscan2
- ACTL6A | c.389G>C p.R130T | Missense Mutation (SNP) | VAF 18/149 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as COSV101199681; called by muse, mutect2, varscan2
- ACTN4 | c.1876-2A>T p.X626_splice | Splice Site (SNP) | VAF 7/35 reads (20%) | catalogued as COSV99400305; called by muse, mutect2, varscan2
- ADCY8 | c.2527G>T p.A843S | Missense Mutation (SNP) | VAF 11/149 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.113); catalogued as COSV99652630; called by muse, mutect2
- ADCY8 | c.1246C>G p.L416V | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53895961, COSV99654440; called by muse, mutect2
- ADCYAP1R1 | c.385C>T p.H129Y | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT tolerated (0.66); PolyPhen benign (0.049); catalogued as COSV100416547; called by muse, mutect2, varscan2
- ADGRB2 | c.1537G>A p.E513K | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.641); catalogued as rs747465394, COSV57071782; called by muse, mutect2, varscan2
- ADGRL2 | c.4171G>A p.E1391K (on ENST00000370717 / NM_001366005.1; = p.E1335K on NM_012302.4) | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated (0.82); PolyPhen benign (0.062); catalogued as COSV99589532; called by muse, mutect2, varscan2
- AEBP1 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.602); catalogued as COSV99788842; called by muse, mutect2, varscan2
- AGPAT3 | c.868C>G p.Q290E | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV99377524; called by muse, mutect2
- AHSP | c.274C>G p.H92D | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.103); catalogued as COSV100176261; called by muse, mutect2, varscan2
- ALKBH6 | c.320C>G p.P107R (on ENST00000252984 / NM_001297701.2; = p.P135R on NM_032878.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/169 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99431122; called by muse, mutect2, varscan2
- ALMS1 | c.875G>T p.R292L | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.043); catalogued as COSV100042682, COSV52506747; called by muse, mutect2, varscan2
- AMHR2 | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as rs553240253, COSV99143258; called by muse, varscan2
- AMOTL1 | c.963G>T p.M321I | Missense Mutation (SNP) | VAF 34/187 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100133830; called by muse, mutect2, varscan2
- ANK1 | c.1752C>G p.I584M | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.729); catalogued as rs565147024, COSV99225551; called by muse, mutect2, varscan2
- ANK3 | c.9557C>G p.P3186R | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.669); catalogued as rs769841771, COSV99780371; called by muse, mutect2, varscan2
- ANO4 | c.55G>C p.E19Q (on ENST00000392977 / NM_001286615.2; = p.V19L on NM_178826.4) | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT tolerated, low confidence (0.27); PolyPhen possibly damaging (0.775); catalogued as COSV100152324, COSV100153039; called by muse, mutect2, varscan2
- AP3S2 | c.130G>A p.D44N | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.292); catalogued as COSV100318530; called by muse, mutect2, varscan2
- APOC3 | c.101G>T p.G34V | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.683); catalogued as COSV99369295; called by muse, mutect2, varscan2
- ARSF | c.346C>G p.L116V | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.021); catalogued as COSV100839526, COSV63839908; called by muse, mutect2, varscan2
- ASXL1 | c.1109C>G p.S370* | Nonsense Mutation (SNP) | VAF 11/83 reads (13%) | catalogued as COSV100039607; called by muse, mutect2, varscan2
- ASXL2 | c.2534C>G p.S845* | Nonsense Mutation (SNP) | VAF 35/194 reads (18%) | catalogued as COSV99711297; called by muse, mutect2, varscan2
- ATAD1 | c.154C>T p.Q52* | Nonsense Mutation (SNP) | VAF 7/53 reads (13%) | catalogued as COSV100058251; called by muse, mutect2, varscan2
- ATF7 | c.842C>G p.S281* (on ENST00000548446 / NM_001366555.2; = p.S270* on NM_006856.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 12/59 reads (20%) | catalogued as COSV100129500; called by muse, mutect2, varscan2
- ATM | c.5119G>A p.E1707K | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs1565474056, COSV99589979; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP12A | c.2842G>C p.D948H | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99517779; called by muse, mutect2, varscan2
- ATP1A1 | c.218C>T p.A73V | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs751968061, COSV99814545; called by muse, mutect2, varscan2
- ATP1B1 | c.571C>G p.P191A | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.355); catalogued as COSV100891056; called by muse, mutect2, varscan2
- ATP2B1 | c.3176C>G p.S1059* | Nonsense Mutation (SNP) | VAF 6/39 reads (15%) | catalogued as COSV99665815; called by muse, mutect2, varscan2
- ATP6V0D2 | c.1010A>G p.Q337R | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99571757; called by muse, mutect2, varscan2
- ATP6V1A | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.006); catalogued as COSV99850181; called by muse, mutect2, varscan2
- ATXN2 | c.1074C>G p.I358M (on ENST00000550104; = p.I198M on NM_002973.4) | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as COSV66485378; called by muse, mutect2, varscan2
- AVP | c.303C>G p.F101L | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV100977780; called by muse, mutect2, varscan2
- BCL6B | c.909C>A p.C303* | Nonsense Mutation (SNP) | VAF 23/178 reads (13%) | catalogued as COSV53429898, COSV99546694; called by muse, mutect2, varscan2
- BIN1 | c.399C>G p.F133L | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as COSV99388117; called by mutect2, varscan2
- BMPR2 | c.1465G>A p.E489K | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101001535; called by muse, mutect2
- BRINP1 | c.807T>G p.C269W | Missense Mutation (SNP) | VAF 21/129 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99775765; called by muse, mutect2, varscan2
- BRINP2 | c.455T>C p.L152P | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100838129; called by muse, mutect2, varscan2
- BRINP3 | c.1274C>A p.S425* | Nonsense Mutation (SNP) | VAF 11/35 reads (31%) | catalogued as COSV66514310, COSV66540055; called by muse, mutect2, varscan2
- C1QTNF7 | c.739C>A p.L247M | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.287); catalogued as COSV99765251; called by muse, mutect2, varscan2
- C1orf131 | c.719A>T p.K240I | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.788); catalogued as COSV100009805; called by muse, mutect2
- C1orf87 | c.8C>T p.S3L | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV100967118, COSV64596259; called by muse, mutect2, varscan2
- C6 | c.2066A>C p.D689A | Missense Mutation (SNP) | VAF 15/146 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99667192; called by muse, mutect2
- C8orf34 | c.1449G>T p.M483I | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as COSV100298423; called by muse, mutect2, varscan2
- CABP1 | c.898G>C p.D300H (on ENST00000316803 / NM_001033677.1; = p.D97H on NM_004276.5) | Missense Mutation (SNP) | VAF 44/256 reads (17%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.97); catalogued as COSV99974704; called by muse, mutect2, varscan2
- CACNA1E | c.5795G>A p.R1932Q | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0.081); catalogued as rs759385572, COSV100703105; called by muse, mutect2, varscan2
- CASP8 | c.458G>T p.G153V (on ENST00000432109 / NM_033355.3; = p.G185V on NM_001228.4) | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); catalogued as COSV51853138, COSV99965995; called by muse, mutect2, varscan2
- CASP8AP2 | c.668C>G p.T223S | Missense Mutation (SNP) | VAF 16/270 reads (6%) | SIFT tolerated (0.45); PolyPhen benign (0.019); catalogued as COSV99387117; called by muse, mutect2
- CBX4 | c.907C>A p.H303N | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV99490385; called by muse, mutect2, varscan2
- CCDC80 | c.1318G>C p.E440Q | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as COSV99244865; called by muse, mutect2, varscan2
- CCDC88A | c.2776G>A p.E926K | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs771833685, COSV55067989; called by muse, mutect2, varscan2
- CCR10 | c.103G>A p.D35N | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.2); catalogued as COSV99226551; called by muse, mutect2, varscan2
- CD163L1 | c.596C>A p.P199Q | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as COSV100550159, COSV58010301; called by muse, mutect2, varscan2
- CDH18 | c.2127C>A p.S709R | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.139); catalogued as COSV99935584; called by muse, varscan2
- CDH9 | c.1108G>T p.V370F | Missense Mutation (SNP) | VAF 15/135 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV50436702; called by muse, mutect2, varscan2
- CDKN2AIP | c.1013C>T p.S338F | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as rs756016744, COSV100187630; called by muse, mutect2, varscan2
- CEACAM4 | c.19G>T p.A7S | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.027); catalogued as COSV55731097, COSV99701080; called by muse, mutect2, varscan2
- CENPF | c.2136G>C p.Q712H | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV100871722; called by muse, mutect2
- CFAP206 | c.1002A>T p.Q334H | Missense Mutation (SNP) | VAF 30/247 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV99739665; called by muse, mutect2, varscan2
- CIP2A | c.313G>T p.G105* | Nonsense Mutation (SNP) | VAF 14/119 reads (12%) | catalogued as COSV99842949; called by muse, mutect2, varscan2
- CKMT1A | c.881A>G p.E294G | Missense Mutation (SNP) | VAF 45/221 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100787724; called by muse, mutect2, varscan2
- CLEC14A | c.370G>C p.E124Q | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.882); catalogued as COSV100643606, COSV60563198; called by muse, mutect2
- CLEC4F | c.808C>A p.Q270K | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.098); catalogued as COSV99713775; called by muse, mutect2, varscan2
- CLTA | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99643637; called by muse, mutect2, varscan2
- CMYA5 | c.2182G>C p.E728Q | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs747115234, COSV101484128; called by muse, mutect2, varscan2
- CMYA5 | c.2831C>G p.P944R | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101484129; called by mutect2, varscan2
- COL26A1 | c.1252G>C p.D418H (on ENST00000313669 / NM_001278563.3; = p.D416H on NM_133457.4) | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.94); catalogued as COSV100561810; called by muse, mutect2, varscan2
- COPB1 | c.1255G>A p.D419N | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99999648; called by muse, mutect2
- CPNE9 | c.745C>T p.Q249* | Nonsense Mutation (SNP) | VAF 14/85 reads (16%) | catalogued as rs773464895, COSV99808310; called by muse, mutect2, varscan2
- CPSF6 | c.970C>G p.P324A | Missense Mutation (SNP) | VAF 16/169 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.027); catalogued as COSV99879412; called by muse, mutect2
- CT55 | c.173A>G p.Y58C | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV52278351, COSV99358896; called by muse, mutect2, varscan2
- CYRIB | c.160C>T p.Q54* | Nonsense Mutation (SNP) | VAF 11/99 reads (11%) | catalogued as COSV100775489; called by muse, mutect2, varscan2
- DAGLA | c.1708G>C p.E570Q | Missense Mutation (SNP) | VAF 34/237 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.099); catalogued as COSV99944444; called by muse, mutect2, varscan2
- DAZAP1 | c.844C>T p.Q282* | Nonsense Mutation (SNP) | VAF 4/38 reads (11%) | catalogued as COSV99245284; called by muse, varscan2
- DCAF12L2 | c.666G>A p.M222I | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs997897823, COSV63580470; called by muse, mutect2, varscan2
- DCT | c.1343C>G p.S448* | Nonsense Mutation (SNP) | VAF 16/49 reads (33%) | catalogued as COSV100986235; called by muse, mutect2, varscan2
- DDC | c.170T>A p.I57N | Missense Mutation (SNP) | VAF 29/174 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as COSV100779450; called by muse, mutect2, varscan2
- DDX24 | c.253G>C p.E85Q | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.235); catalogued as COSV100427978, COSV58212952; called by muse, mutect2, varscan2
- DENND6B | c.264C>A p.C88* | Nonsense Mutation (SNP) | VAF 9/78 reads (12%) | catalogued as COSV101306082; called by muse, mutect2, varscan2
- DGKD | c.1803G>C p.Q601H (on ENST00000264057 / NM_152879.3; = p.Q557H on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.396); catalogued as COSV99896536; called by muse, mutect2, varscan2
- DHX34 | c.2338G>T p.A780S | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as COSV100169639; called by muse, mutect2, varscan2
- DICER1 | c.4070A>G p.Y1357C | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV100602182; called by muse, mutect2, varscan2
- DIP2A | c.4641G>C p.E1547D | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100595932; called by muse, mutect2, varscan2
- DLL4 | c.1285C>A p.R429S | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.485); catalogued as COSV99989854; called by mutect2, varscan2
- DNAH2 | c.4156A>C p.K1386Q | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV101209391; called by muse, mutect2, varscan2
- DNAH3 | c.8993A>T p.D2998V | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99767983; called by muse, mutect2, varscan2
- DNAH5 | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as COSV54226117; called by muse, mutect2, varscan2
- DNAJC9 | c.222G>C p.Q74H | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV99654756; called by muse, mutect2, varscan2
- DUOX2 | c.3870G>C p.Q1290H | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as rs771417585, COSV101199786; called by muse, mutect2, varscan2
- DUOXA2 | c.658G>A p.G220R | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as COSV99973263; called by muse, mutect2, varscan2
- DUSP23 | c.409G>C p.E137Q | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); catalogued as COSV100929128; called by muse, mutect2, varscan2
- DYSF | c.4061C>G p.S1354C | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99247724; called by muse, mutect2, varscan2
- ECT2L | c.1105G>C p.E369Q | Missense Mutation (SNP) | VAF 32/193 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); catalogued as COSV100872005; called by muse, mutect2, varscan2
- EDARADD | c.449A>G p.Y150C (on ENST00000334232 / NM_145861.4; = p.Y140C on NM_080738.4) | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1031441787, COSV100512803, COSV62064154; called by muse, mutect2, varscan2
- EDC3 | c.372G>C p.K124N | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.343); catalogued as COSV100165983; called by muse, mutect2, varscan2
- EEA1 | c.1979C>T p.A660V | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.223); catalogued as rs1199599041, COSV100467798; called by muse, mutect2, varscan2
- ELL2 | c.1007G>A p.R336Q | Missense Mutation (SNP) | VAF 29/202 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1283382779, COSV52982061; called by muse, mutect2, varscan2
- EPHA8 | c.2077C>A p.H693N | Missense Mutation (SNP) | VAF 26/199 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV99384999; called by muse, mutect2, varscan2
- EPS15 | c.2575G>T p.A859S | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100869556; called by muse, mutect2, varscan2
- ERF | c.306C>G p.F102L | Missense Mutation (SNP) | VAF 50/281 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99724692; called by muse, mutect2, varscan2
- ESAM | c.343G>T p.G115C | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as COSV99631884; called by muse, mutect2, varscan2
- ETFB | c.750G>C p.K250N | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.712); catalogued as COSV100164367; called by muse, mutect2, varscan2
- FAM47A | c.1469G>T p.S490I | Missense Mutation (SNP) | VAF 20/156 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.038); catalogued as COSV100649936; called by muse, varscan2
- FAM9C | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 22/137 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.636); catalogued as COSV100452824; called by muse, mutect2, varscan2
- FCRL3 | c.1102C>T p.L368F | Missense Mutation (SNP) | VAF 16/167 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.345); catalogued as rs915646866, COSV100943303; called by muse, mutect2
- FCRL6 | c.116G>C p.C39S | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1225011194, COSV100220220; called by muse, mutect2, varscan2
- FEM1A | c.1599G>C p.K533N | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.091); catalogued as COSV54163905; called by muse, mutect2, varscan2
- FGFR2 | c.1977G>C p.K659N | Missense Mutation (SNP) | VAF 32/176 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as CM020143, COSV60638719, COSV60655029; called by muse, varscan2
- FLNC | c.4195G>A p.D1399N | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100368225; called by muse, mutect2, varscan2
- FNDC3B | c.87G>T p.L29F | Missense Mutation (SNP) | VAF 18/169 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.134); catalogued as rs1165019148, COSV100394301; called by muse, mutect2, varscan2
- FOXM1 | c.1424G>C p.R475T | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.786); catalogued as COSV100700863; called by muse, mutect2, varscan2
- FRY | c.1974G>C p.W658C | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV100969370; called by muse, mutect2, varscan2
- FSTL5 | c.9G>T p.K3N | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.021); catalogued as COSV100056435, COSV100061310; called by muse, mutect2, varscan2
- FTO | c.1480T>C p.S494P | Missense Mutation (SNP) | VAF 78/275 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.69); catalogued as COSV99193137; called by muse, mutect2, varscan2
- FUT9 | c.325C>A p.H109N | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.398); catalogued as COSV100133759; called by muse, mutect2, varscan2
- FYCO1 | c.1886T>C p.V629A | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV99945775; called by muse, mutect2, varscan2
- GJA1 | c.1018G>A p.D340N | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.024); catalogued as COSV56997883, COSV99247051; called by muse, mutect2, varscan2
- GLI3 | c.1069C>G p.L357V | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.071); catalogued as COSV101229906, COSV67891967; called by muse, mutect2
- GPR156 | c.2218C>G p.Q740E | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV100251418; called by muse, mutect2, varscan2
- GRIA1 | c.86G>T p.G29V | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53620407, COSV53622268, COSV99600345; called by muse, mutect2, varscan2
- GRIA3 | c.2224G>A p.E742K | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV99990500; called by muse, mutect2, varscan2
- GRIP2 | c.793G>A p.E265K (on ENST00000619221; = p.E168K on NM_001080423.4) | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as COSV56119818, COSV56119866; called by muse, mutect2, varscan2
- GUCY2C | c.1675G>C p.G559R | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV53788799; called by muse, mutect2, varscan2
- HAO2 | c.41G>A p.R14Q | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs760870079, COSV58038381; called by muse, mutect2, varscan2
- HDC | c.1924T>A p.F642I | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.727); catalogued as COSV99984105; called by muse, mutect2, varscan2
- HDC | c.1326C>G p.D442E | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.034); catalogued as COSV99984108; called by muse, mutect2, varscan2
- HEATR1 | c.1063G>T p.V355F | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100857661; called by muse, mutect2, varscan2
- HEATR6 | c.3403G>T p.A1135S | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.626); catalogued as COSV99482386; called by muse, mutect2, varscan2
- HEATR6 | c.3402G>A p.M1134I | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV99482388; called by muse, mutect2, varscan2
- HEPH | c.1423C>A p.R475S (on ENST00000343002; = p.R208S on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as COSV57962448, COSV57968664; called by muse, mutect2, varscan2
- HERC1 | c.80C>G p.S27C | Missense Mutation (SNP) | VAF 25/178 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.841); catalogued as COSV101496619, COSV71250222; called by muse, mutect2, varscan2
- HHAT | c.397C>G p.Q133E | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.019); catalogued as COSV99804712; called by muse, mutect2, varscan2
- HIPK1 | c.2143C>A p.Q715K | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.58); PolyPhen benign (0.012); catalogued as COSV100479204; called by muse, mutect2, varscan2
- HMCN1 | c.6493C>G p.Q2165E | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.515); catalogued as rs1239876111, COSV54947972, COSV99630322; called by muse, mutect2, varscan2
- HMCN1 | c.14267-1G>T p.X4756_splice | Splice Site (SNP) | VAF 24/98 reads (24%) | catalogued as COSV99630324; called by muse, mutect2, varscan2
- HS6ST3 | c.1398C>A p.S466R | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV100940789; called by muse, mutect2, varscan2
- HSD17B3 | c.580C>G p.L194V | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.301); catalogued as COSV100931273; called by muse, mutect2, varscan2
- HYOU1 | c.2966G>C p.G989A | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.014); catalogued as COSV101345619; called by muse, mutect2, varscan2
- IFT57 | c.428A>T p.H143L | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.077); catalogued as COSV99197656; called by muse, mutect2, varscan2
- IP6K2 | c.451G>C p.E151Q | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV100152003; called by muse, mutect2
- IQCE | c.1630G>A p.E544K | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100383466; called by muse, mutect2, varscan2
- ITPR2 | c.2764C>T p.H922Y | Missense Mutation (SNP) | VAF 22/200 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.04); catalogued as COSV101190015; called by muse, mutect2, varscan2
- ITPR3 | c.4351G>C p.V1451L | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.035); catalogued as COSV100967478; called by muse, mutect2, varscan2
- JOSD1 | c.440G>C p.G147A | Missense Mutation (SNP) | VAF 17/144 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV99320155; called by muse, mutect2, varscan2
- KALRN | c.1859G>A p.R620Q | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.991); catalogued as COSV53782237; called by muse, mutect2, varscan2
- KCNC4 | c.857G>A p.G286D | Missense Mutation (SNP) | VAF 39/286 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.845); catalogued as COSV100873631; called by muse, mutect2, varscan2
- KCNK10 | c.1447G>T p.E483* | Nonsense Mutation (SNP) | VAF 16/57 reads (28%) | catalogued as COSV100068530, COSV56638780; called by muse, mutect2, varscan2
- KCTD10 | c.518C>T p.S173L | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.609); catalogued as COSV57326342; called by muse, mutect2
- KCTD21 | c.293A>G p.E98G | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.694); catalogued as COSV100399739; called by muse, mutect2, varscan2
- KIFC2 | c.1084C>G p.Q362E | Missense Mutation (SNP) | VAF 45/192 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.087); catalogued as rs766606286, COSV100023839; called by muse, mutect2, varscan2
- KLHL4 | c.406G>C p.E136Q | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV100909687, COSV104427006; called by muse, mutect2, varscan2
- KMT2C | c.791A>T p.Q264L | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.6); catalogued as COSV100072657; called by muse, mutect2, varscan2
- KRIT1 | c.1875C>G p.F625L | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV100388795; called by muse, mutect2, varscan2
- KTN1 | c.1289G>A p.R430K | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV101255251; called by muse, mutect2, varscan2
- LACRT | c.107G>T p.G36V | Missense Mutation (SNP) | VAF 63/407 reads (15%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV57688795, COSV99143848; called by muse, mutect2, varscan2
- LACRT | c.106G>T p.G36W | Missense Mutation (SNP) | VAF 62/408 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.609); catalogued as COSV57687749; called by muse, mutect2, varscan2
- LGALS13 | c.192G>C p.M64I | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.841); catalogued as COSV99694948; called by muse, mutect2, varscan2
- LMX1A | c.403T>C p.F135L | Missense Mutation (SNP) | VAF 19/159 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV99672454; called by muse, mutect2, varscan2
- LPA | c.6108G>C p.M2036I | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV100307132; called by muse, mutect2, varscan2
- LRP10 | c.128A>C p.Q43P | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.522); catalogued as COSV100612399; called by muse, mutect2, varscan2
- LRRC31 | c.823+2T>C p.X275_splice | Splice Site (SNP) | VAF 10/132 reads (8%) | catalogued as COSV99246772; called by muse, mutect2
- LRRC66 | c.1690G>T p.A564S | Missense Mutation (SNP) | VAF 20/173 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.033); catalogued as COSV58633914, COSV58637046; called by muse, mutect2, varscan2
- MACF1 | c.638G>C p.G213A | Missense Mutation (SNP) | VAF 12/110 reads (11%) | catalogued as COSV100484912; called by muse, mutect2, varscan2
- MAG | c.554T>A p.V185E | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.459); catalogued as COSV100727882; called by muse, mutect2, varscan2
- MAGEA11 | c.989C>A p.P330H | Missense Mutation (SNP) | VAF 35/226 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); catalogued as COSV100290402; called by muse, mutect2, varscan2
- MAGEB1 | c.44G>T p.R15L | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100975005; called by muse, mutect2, varscan2
- MAIP1 | c.767A>G p.E256G | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as COSV99705275; called by muse, mutect2, varscan2
- MAML2 | c.1559C>T p.S520L | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1165827725, COSV101594132; called by muse, mutect2
- MAOB | c.479C>G p.S160C | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs371973652, COSV100956087; called by muse, mutect2, varscan2
- MAP3K1 | c.2134G>T p.G712C | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101266895; called by muse, mutect2, varscan2
- MARK4 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 37/259 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as COSV99488379; called by muse, mutect2, varscan2
- MAST4 | c.2593G>C p.E865Q (on ENST00000403625 / NM_001164664.2; = p.E676Q on NM_015183.3) | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99844504; called by muse, mutect2, varscan2
- MB21D2 | c.931C>G p.Q311E | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.403); catalogued as rs988241015, COSV66661548, COSV66661553; called by muse, mutect2, varscan2
- MDC1 | c.5095G>C p.E1699Q | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.959); catalogued as COSV100902857; called by muse, mutect2, varscan2
- MDN1 | c.14478C>A p.S4826R | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as COSV101021441; called by muse, mutect2, varscan2
- MDN1 | c.2431G>C p.E811Q | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.444); catalogued as COSV101021442; called by muse, mutect2, varscan2
- MEGF10 | c.140C>T p.S47L | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV99175015; called by muse, mutect2, varscan2
- MEP1A | c.187-1G>A p.X63_splice | Splice Site (SNP) | VAF 11/112 reads (10%) | catalogued as COSV100042615, COSV100042800; called by muse, mutect2, varscan2
- MICAL3 | c.3780C>G p.I1260M | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV71588932; called by muse, mutect2, varscan2
- MIGA1 | c.604C>G p.P202A | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100889782; called by muse, mutect2, varscan2
- MISP | c.1976G>T p.R659L | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99296878; called by muse, mutect2, varscan2
- MMEL1 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 32/201 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0.024); catalogued as rs751529106, COSV56518421; called by muse, mutect2, varscan2
- MMP10 | c.1300C>A p.P434T | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0.005); catalogued as COSV99666585; called by muse, mutect2, varscan2
- MMP25 | c.164C>A p.P55H | Missense Mutation (SNP) | VAF 47/202 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.796); catalogued as COSV100339469; called by muse, mutect2, varscan2
- MON2 | c.1036G>C p.D346H | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99742774; called by muse, mutect2, varscan2
- MOXD1 | c.896C>A p.P299Q | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs374751992, COSV100381635; called by muse, mutect2, varscan2
- MTDH | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100292608; called by muse, mutect2, varscan2
- MUC16 | c.40608C>T p.L13536= | Splice Region (SNP) | VAF 31/133 reads (23%) | catalogued as COSV101109925; called by muse, mutect2, varscan2
- MYCBP2 | c.6829C>G p.Q2277E (on ENST00000357337; = p.Q2315E on NM_015057.5) | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.68); catalogued as COSV62022985; called by muse, mutect2, varscan2
- MYCT1 | c.619T>A p.Y207N | Missense Mutation (SNP) | VAF 15/146 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.165); catalogued as COSV65891750; called by muse, mutect2
- MYH4 | c.909G>T p.M303I | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs1029456820, COSV99700257; called by muse, mutect2
- MYH6 | c.4489C>A p.L1497I | Missense Mutation (SNP) | VAF 21/157 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100676664; called by muse, mutect2, varscan2
- MYH8 | c.2038G>T p.E680* | Nonsense Mutation (SNP) | VAF 17/62 reads (27%) | catalogued as COSV101238448, COSV67959805; called by muse, mutect2, varscan2
- NCAM2 | c.1522T>A p.S508T | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.1); catalogued as COSV99523375; called by muse, mutect2, varscan2
- NCOA2 | c.2104G>T p.D702Y | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101476011; called by muse, mutect2, varscan2
- NCOA2 | c.1801G>C p.E601Q | Missense Mutation (SNP) | VAF 21/139 reads (15%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV101476012; called by muse, mutect2, varscan2
- NECTIN3 | c.256A>G p.I86V | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.28); catalogued as rs767088764, COSV100162493; called by mutect2, varscan2
- NF1 | c.623C>A p.A208E | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.764); catalogued as COSV100647293, COSV62205212; called by muse, mutect2
- NLRP2 | c.3157G>C p.E1053Q | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.011); catalogued as COSV54759398, COSV99672332, COSV99672574; called by muse, mutect2, varscan2
- NNT | c.1372C>G p.L458V | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV99239032; called by muse, mutect2, varscan2
- NPLOC4 | c.257C>T p.S86L | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV100480965; called by muse, mutect2, varscan2
- NSD3 | c.1198G>C p.E400Q | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.019); catalogued as COSV100388707; called by muse, mutect2, varscan2
- NUP42 | c.1186G>C p.E396Q | Missense Mutation (SNP) | VAF 29/148 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.085); catalogued as COSV99331062; called by muse, mutect2, varscan2
- OR10G2 | c.823G>T p.G275W | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101606959; called by muse, mutect2, varscan2
- OR10P1 | c.603G>C p.M201I | Missense Mutation (SNP) | VAF 11/145 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.062); catalogued as COSV100548176; called by muse, mutect2
- OR1S1 | c.808G>T p.G270C | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100515416, COSV58708019; called by muse, mutect2, varscan2
- OR1S1 | c.809G>T p.G270V | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100515417; called by muse, mutect2, varscan2
- OR4D6 | c.20C>A p.T7N | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.891); catalogued as COSV100271728; called by muse, mutect2
- OR51I1 | c.503T>A p.L168Q | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100971398; called by muse, mutect2, varscan2
- OR52A5 | c.512A>T p.H171L | Missense Mutation (SNP) | VAF 15/167 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV100263473; called by muse, mutect2
- OR52B6 | c.776C>A p.T259N | Missense Mutation (SNP) | VAF 30/163 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100798496; called by muse, mutect2, varscan2
- OR5H15 | c.216G>T p.W72C | Missense Mutation (SNP) | VAF 23/185 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.027); catalogued as COSV100736683; called by muse, mutect2, varscan2
- OR9K2 | c.299C>T p.S100F (on ENST00000305377; = p.S78F on NM_001005243.1) | Missense Mutation (SNP) | VAF 28/166 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV100543852, COSV59532370, COSV59533391; called by muse, mutect2
- OSBPL2 | c.468G>C p.L156F (on ENST00000313733 / NM_144498.4; = p.L144F on NM_014835.4) | Missense Mutation (SNP) | VAF 24/169 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100569285; called by muse, mutect2, varscan2
- OTOR | c.202G>T p.V68L | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as COSV99856233; called by muse, mutect2
- PABPC5 | c.901G>T p.G301W | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV57041695; called by muse, mutect2, varscan2
- PARPBP | c.704G>T p.G235V | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100569213; called by muse, mutect2, varscan2
- PCDH15 | c.1619C>A p.S540* | Nonsense Mutation (SNP) | VAF 23/111 reads (21%) | catalogued as COSV100221904; called by muse, mutect2, varscan2
- PCDHAC1 | c.74C>A p.S25* | Nonsense Mutation (SNP) | VAF 10/52 reads (19%) | catalogued as COSV99166724; called by muse, mutect2, varscan2
- PCDHAC1 | c.367C>G p.L123V | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as rs1262444613, COSV99166725; called by muse, mutect2, varscan2
- PCDHB3 | c.1732C>T p.R578W | Missense Mutation (SNP) | VAF 25/177 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.233); catalogued as rs1554272550; called by muse, mutect2, varscan2
- PCNT | c.1795G>C p.E599Q | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.502); catalogued as COSV100855616; called by muse, mutect2, varscan2
- PCNT | c.3634G>C p.D1212H | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.141); catalogued as COSV100855617; called by muse, mutect2
- PDZRN3 | c.925G>T p.G309C | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55203975, COSV99730093; called by muse, mutect2, varscan2
- PENK | c.653G>T p.G218V | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV100152352; called by muse, mutect2, varscan2
- PENK | c.652G>T p.G218C | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59242519; called by muse, mutect2, varscan2
- PHC1 | c.1208A>T p.H403L | Missense Mutation (SNP) | VAF 22/158 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.44); catalogued as COSV101418632; called by muse, mutect2, varscan2
- PHF20 | c.2848C>G p.Q950E | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as COSV100926624; called by muse, mutect2, varscan2
- PHF8 | c.1268G>A p.R423K (on ENST00000357988 / NM_001184896.1; = p.R387K on NM_015107.3) | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.93); PolyPhen benign (0.039); catalogued as COSV100154323; called by muse, mutect2, varscan2
- PIGG | c.247G>A p.G83R | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as rs781884643, COSV99573973; called by muse, mutect2
- PIGG | c.248G>T p.G83V | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99573974; called by muse, mutect2, varscan2
- PIH1D2 | c.272G>C p.G91A | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99735446; called by muse, mutect2, varscan2
- PIP5K1B | c.209G>A p.S70N | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.465); catalogued as COSV99599029; called by muse, mutect2, varscan2
- PIWIL1 | c.1213G>T p.D405Y | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV55344254; called by muse, mutect2, varscan2
- PLCZ1 | c.1355A>T p.N452I | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99856461; called by muse, mutect2, varscan2
- POU4F3 | c.116C>A p.P39Q | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.916); catalogued as COSV100047093; called by muse, mutect2, varscan2
- PPFIA3 | c.1219G>C p.E407Q | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.667); catalogued as rs772193734, COSV100494982; called by muse, mutect2, varscan2
- PPP1R2 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.404); catalogued as COSV100113297, COSV100113367; called by muse, mutect2, varscan2
- PPP4R4 | c.87C>G p.I29M | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.096); catalogued as COSV100175746; called by muse, mutect2
- PRDM1 | c.1090G>T p.G364C | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV100958832; called by muse, mutect2, varscan2
- PRLR | c.1129C>A p.P377T | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs755466887, COSV99184447; called by muse, mutect2, varscan2
- PSMB8 | c.581C>T p.S194L (on ENST00000374882 / NM_148919.4; = p.S190L on NM_004159.5) | Missense Mutation (SNP) | VAF 21/183 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.23); catalogued as COSV100841227; called by muse, mutect2, varscan2
- PSMD2 | c.272C>G p.S91* | Nonsense Mutation (SNP) | VAF 8/98 reads (8%) | catalogued as COSV100031822, COSV100031823; called by muse, mutect2
- PSMD2 | c.1319T>G p.I440S | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV100031824; called by muse, varscan2
- PTGDR | c.324C>G p.F108L | Missense Mutation (SNP) | VAF 31/218 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100035608; called by muse, mutect2, varscan2
- PTPN2 | c.808A>G p.M270V | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.058); catalogued as rs199581316, COSV100518597; called by muse, mutect2, varscan2
- QTRT2 | c.44G>A p.G15E | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199639009, COSV99846928; called by muse, mutect2, varscan2
- RAB13 | c.475G>A p.D159N | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.346); catalogued as COSV99665747; called by muse, mutect2, varscan2
- RAB3GAP2 | c.2950G>C p.E984Q | Missense Mutation (SNP) | VAF 37/166 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV100741301; called by muse, mutect2, varscan2
- RASGRF1 | c.345del p.D116Ifs*24 | Frame Shift Del (DEL) | VAF 39/250 reads (16%) | catalogued as COSV101369814; called by mutect2, pindel, varscan2
- RASIP1 | c.2374C>G p.Q792E | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated (0.7); PolyPhen benign (0.402); catalogued as rs201080880, COSV99710851; called by muse, mutect2, varscan2
- RBAK | c.1000C>G p.Q334E | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.981); catalogued as rs762830152, COSV100806681; called by muse, mutect2, varscan2
- RBBP6 | c.304-1G>C p.X102_splice | Splice Site (SNP) | VAF 7/90 reads (8%) | catalogued as COSV60505162; called by muse, mutect2
- RORC | c.79G>C p.E27Q | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100561959; called by muse, mutect2, varscan2
- RPS6KA3 | c.1984G>A p.V662I | Missense Mutation (SNP) | VAF 41/260 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as COSV101084434; called by muse, mutect2, varscan2
- RSPO1 | c.321C>A p.S107R | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV100740613; called by muse, mutect2, varscan2
- RUNX1T1 | c.700C>G p.L234V (on ENST00000265814 / NM_001198628.1; = p.L207V on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/174 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs1355519811, COSV56142691, COSV99752577; called by muse, mutect2, varscan2
- RYR3 | c.1204C>A p.R402S | Missense Mutation (SNP) | VAF 30/187 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.279); catalogued as COSV101212937, COSV66785134; called by muse, mutect2, varscan2
- SBNO1 | c.2230G>A p.E744K (on ENST00000420886; = p.E743K on NM_018183.5) | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs866852232, COSV99929294; called by muse, mutect2, varscan2
- SCGB1D4 | c.27G>T p.M9I | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as COSV100669606; called by muse, mutect2, varscan2
- SCMH1 | c.1329C>G p.I443M (on ENST00000326197 / NM_001031694.2; = p.I396M on NM_012236.4) | Missense Mutation (SNP) | VAF 18/230 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.562); catalogued as COSV100401847, COSV100401875; called by muse, mutect2
- SEC24D | c.2341G>A p.E781K | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.72); catalogued as rs149595481; called by muse, mutect2, varscan2
- SEC31A | c.1574C>T p.A525V | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV100021942; called by muse, mutect2, varscan2
- SEL1L | c.1504G>C p.D502H | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100377950; called by muse, mutect2, varscan2
- SETD2 | c.6804G>C p.Q2268H | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100339181; called by muse, mutect2, varscan2
- SGK2 | c.652A>C p.R218= | Splice Region (SNP) | VAF 14/81 reads (17%) | catalogued as COSV100414683; called by muse, mutect2, varscan2
- SH3PXD2B | c.2528C>T p.S843F | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.191); catalogued as COSV61130695; called by muse, mutect2, varscan2
- SLC26A9 | c.1088T>C p.V363A | Missense Mutation (SNP) | VAF 42/280 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.389); catalogued as COSV100536431; called by muse, mutect2, varscan2
- SLC30A10 | c.1345G>T p.D449Y | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.293); catalogued as COSV100751525; called by muse, mutect2, varscan2
- SLC39A3 | c.418G>T p.G140C | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.432); catalogued as COSV99514220; called by muse, mutect2, varscan2
- SLC44A5 | c.330G>C p.Q110H | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.214); catalogued as COSV100902153; called by muse, mutect2
- SLC6A15 | c.1309C>T p.Q437* | Nonsense Mutation (SNP) | VAF 10/55 reads (18%) | catalogued as COSV99880789; called by muse, mutect2, varscan2
- SLIT3 | c.3136C>T p.Q1046* | Nonsense Mutation (SNP) | VAF 18/106 reads (17%) | catalogued as COSV100268064; called by muse, mutect2, varscan2
- SMAD9 | c.1025G>A p.G342E (on ENST00000379826 / NM_001127217.3; = p.G305E on NM_005905.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.591); catalogued as COSV100614774; called by muse, mutect2, varscan2
- SMCO3 | c.611C>T p.S204L | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.118); catalogued as COSV99660733; called by muse, mutect2, varscan2
- SMG8 | c.1205C>G p.S402* | Nonsense Mutation (SNP) | VAF 29/133 reads (22%) | catalogued as COSV99958879; called by muse, mutect2, varscan2
- SMG9 | c.1474G>A p.E492K | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.352); catalogued as rs1032908644, COSV54213893; called by muse, mutect2, varscan2
- SPAG9 | c.331G>C p.E111Q | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); catalogued as COSV100005329; called by muse, mutect2, varscan2
- SPATA16 | c.1583A>G p.Q528R | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.523); catalogued as COSV100651324; called by muse, mutect2, varscan2
- SPTA1 | c.1450G>T p.D484Y | Missense Mutation (SNP) | VAF 19/144 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100935090, COSV63756326; called by muse, mutect2, varscan2
- SSH2 | c.2850G>C p.Q950H | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV99282246; called by muse, mutect2, varscan2
- STAC | c.364G>T p.D122Y | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99830139; called by muse, mutect2, varscan2
- SUPT16H | c.3057G>C p.K1019N | Missense Mutation (SNP) | VAF 25/147 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV99251156; called by muse, mutect2, varscan2
- SUPT20H | c.829C>T p.Q277* (on ENST00000350612 / NM_001014286.3; = p.Q278* on NM_017569.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 12/63 reads (19%) | catalogued as COSV100634712; called by muse, varscan2
- SYNGAP1 | c.1397C>G p.S466* | Nonsense Mutation (SNP) | VAF 32/134 reads (24%) | catalogued as COSV99538525; called by muse, mutect2, varscan2
- SYT11 | c.430A>G p.S144G | Missense Mutation (SNP) | VAF 21/201 reads (10%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.824); catalogued as COSV100851316; called by muse, mutect2, varscan2
- TACC2 | c.1085C>G p.S362C | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.06); catalogued as rs995053150, COSV100552533; called by muse, mutect2, varscan2
- TARDBP | c.124C>T p.R42C | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as COSV99534288; called by muse, mutect2, varscan2
- TBKBP1 | c.59G>C p.S20T | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as COSV100659160; called by muse, mutect2, varscan2
- TBX15 | c.562G>T p.A188S (on ENST00000369429 / NM_001330677.2; = p.A82S on NM_152380.3) | Missense Mutation (SNP) | VAF 31/275 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99254281; called by muse, mutect2, varscan2
- TDRD7 | c.2971G>A p.E991K | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV100795676; called by muse, mutect2, varscan2
- TDRD9 | c.2311G>A p.D771N | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.253); catalogued as COSV100175228; called by muse, mutect2, varscan2
- TENM1 | c.4111G>T p.A1371S | Missense Mutation (SNP) | VAF 29/245 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.076); catalogued as COSV100950236; called by muse, mutect2, varscan2
- TFAP2B | c.875G>T p.G292V | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99540301; called by muse, mutect2, varscan2
- TGFBR2 | c.583C>T p.Q195* | Nonsense Mutation (SNP) | VAF 7/35 reads (20%) | catalogued as COSV99847272; called by muse, mutect2, varscan2
- THSD4 | c.781C>T p.H261Y | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.196); catalogued as COSV99965820; called by muse, mutect2, varscan2
- TIMD4 | c.395A>T p.Q132L | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as COSV99192667; called by muse, mutect2, varscan2
- TJP1 | c.2803G>C p.E935Q | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated, low confidence (0.23); PolyPhen possibly damaging (0.755); catalogued as COSV100632773; called by muse, mutect2, varscan2
- TLL2 | c.567G>C p.K189N | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.87); PolyPhen probably damaging (0.998); catalogued as COSV100780327; called by muse, mutect2, varscan2
- TM6SF1 | c.355C>T p.H119Y | Missense Mutation (SNP) | VAF 59/426 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV51946630, COSV99362696; called by muse, mutect2, varscan2
- TNK2 | c.1324G>A p.V442M | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as rs1393270307, COSV100361420; called by muse, mutect2, varscan2
- TNR | c.145G>A p.G49R | Missense Mutation (SNP) | VAF 28/351 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.691); catalogued as COSV99689985; called by muse, mutect2
- TOR1B | c.300G>C p.K100N | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.241); catalogued as COSV99400145, COSV99400206; called by muse, mutect2, varscan2
- TRIM24 | c.1490G>C p.R497T | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.307); catalogued as COSV100630997; called by muse, mutect2, varscan2
- TRIO | c.1457A>G p.H486R | Missense Mutation (SNP) | VAF 24/236 reads (10%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.966); catalogued as rs1230769653, COSV100710468; called by muse, mutect2, varscan2
- TRPC3 | c.2405G>A p.C802Y (on ENST00000379645 / NM_001366479.2; = p.C729Y on NM_003305.2) | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.492); catalogued as COSV99312767; called by muse, mutect2
- TSPEAR | c.881T>C p.L294P | Missense Mutation (SNP) | VAF 29/208 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100554034; called by muse, mutect2, varscan2
- TUBGCP4 | c.379G>T p.D127Y | Missense Mutation (SNP) | VAF 20/145 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as COSV99539116; called by muse, mutect2, varscan2
- TUT1 | c.2083G>A p.E695K | Missense Mutation (SNP) | VAF 90/667 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV99545360; called by muse, mutect2, varscan2
- TUT7 | c.2128G>A p.E710K | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.129); catalogued as COSV52895091, COSV99463143; called by muse, mutect2, varscan2
- TXNDC2 | c.1156G>C p.E386Q (on ENST00000306084 / NM_001098529.2; = p.E319Q on NM_032243.6) | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0.306); catalogued as COSV100046224, COSV60152408; called by muse, mutect2, varscan2
- UBP1 | c.810C>G p.I270M | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.196); catalogued as COSV99372732; called by muse, mutect2, varscan2
- UNC45A | c.1060C>G p.L354V | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV101265910; called by muse, mutect2, varscan2
- UNC79 | c.7550C>T p.T2517I (on ENST00000393151 / NM_001346218.2; = p.T2340I on NM_020818.5) | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56376467, COSV99828230; called by muse, mutect2, varscan2
- URGCP | c.247G>C p.E83Q (on ENST00000453200 / NM_001077663.3; = p.E74Q on NM_017920.4) | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.367); catalogued as COSV99787426; called by muse, varscan2
- USH2A | c.11179G>C p.G3727R | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.484); catalogued as COSV100236311; called by muse, mutect2, varscan2
- USP13 | c.1453C>G p.Q485E | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.829); catalogued as COSV99831271; called by muse, mutect2, varscan2
- USP54 | c.1782G>T p.R594S | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100161165; called by muse, mutect2, varscan2
- USP9X | c.1895G>C p.R632T | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV100199423; called by muse, mutect2, varscan2
- UTP14A | c.2203G>C p.E735Q | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.566); catalogued as COSV100928969; called by muse, mutect2, varscan2
- VCPIP1 | c.1399C>T p.H467Y | Missense Mutation (SNP) | VAF 33/212 reads (16%) | SIFT tolerated (0.7); PolyPhen benign (0.039); catalogued as COSV100125653; called by muse, mutect2, varscan2
- VPS50 | c.19C>G p.L7V | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.332); catalogued as COSV99298232; called by muse, mutect2, varscan2
- WNK4 | c.803G>A p.R268Q | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1449271462, COSV53821808; called by muse, mutect2
- WWC1 | c.637G>T p.E213* | Nonsense Mutation (SNP) | VAF 11/72 reads (15%) | catalogued as COSV99514039; called by muse, mutect2, varscan2
- XPO7 | c.2496C>G p.I832M | Missense Mutation (SNP) | VAF 56/239 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.26); catalogued as COSV99381432; called by muse, mutect2, varscan2
- ZC3H12B | c.772G>C p.E258Q | Missense Mutation (SNP) | VAF 28/193 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100161797; called by muse, mutect2, varscan2
- ZFYVE26 | c.7283G>C p.C2428S | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV100720476; called by muse, mutect2, varscan2
- ZNF227 | c.929C>G p.S310C | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV100480435; called by muse, mutect2, varscan2
- ZNF320 | c.1321C>T p.H441Y | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV101206870, COSV67088990; called by muse, mutect2, varscan2
- ZNF320 | c.152C>G p.S51C | Missense Mutation (SNP) | VAF 17/164 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.147); catalogued as COSV101206872; called by muse, mutect2, varscan2
- ZNF483 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as COSV100492942, COSV58515387; called by muse, mutect2, varscan2
- ZNF536 | c.2985G>T p.Q995H | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV100835316, COSV62833445; called by muse, mutect2, varscan2
- ZNF560 | c.818C>G p.S273C | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.73); catalogued as COSV100038692, COSV56871200; called by muse, mutect2, varscan2
- ZNF585B | c.1552G>T p.G518W | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100459476; called by muse, mutect2, varscan2
- ZNF608 | c.2644G>C p.E882Q | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100101818, COSV60438455; called by muse, mutect2, varscan2
- ZNF671 | c.65G>A p.R22Q | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs879083287, COSV100234914, COSV100235118; called by mutect2, varscan2
- ZNF816 | c.1816G>C p.A606P | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as COSV99554605; called by muse, mutect2, varscan2
- ZSWIM2 | c.1299A>C p.L433F | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.021); catalogued as COSV99720270; called by muse, mutect2, varscan2
- AMHR2 | c.186dup p.G63Wfs*21 | Frame Shift Ins (INS) | VAF 6/36 reads (17%) | called by pindel, varscan2
- BAIAP3 | c.355C>T p.P119S | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.015); called by muse, mutect2
- CNTNAP3 | c.3814A>T p.R1272* | Nonsense Mutation (SNP) | VAF 14/407 reads (3%) | called by muse, mutect2
- FCGBP | c.12166G>A p.G4056S | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.72); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- IFNA13 | c.139A>G p.R47G | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2
- IGKV1-16 | c.299T>G p.L100R | Missense Mutation (SNP) | VAF 26/224 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- MED29 | c.550del p.V184Sfs*58 (on ENST00000615911; = p.V163Sfs*58 on NM_017592.4) | Frame Shift Del (DEL) | VAF 9/68 reads (13%) | called by mutect2, pindel, varscan2
- PSMB10 | c.432_446del p.T145_L149del | In Frame Del (DEL) | VAF 14/128 reads (11%) | called by mutect2, pindel
- RSPH10B | c.400-1G>C p.X134_splice | Splice Site (SNP) | VAF 10/124 reads (8%) | called by muse, mutect2
- ADCY5 | c.1425C>T p.I475= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as rs757156390, CM1515047, COSV59198500, COSV59203348; called by muse, mutect2, varscan2
- ADGRE1 | c.594C>T p.F198= | Silent (SNP) | VAF 42/221 reads (19%) | catalogued as COSV51677293; called by muse, mutect2, varscan2
- ALPK1 | c.240G>A p.L80= | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as COSV99454276; called by muse, mutect2, varscan2
- ARHGEF40 | c.3279G>C p.L1093= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as COSV100070407; called by muse, mutect2, varscan2
- ARHGEF9 | c.435G>A p.L145= | Silent (SNP) | VAF 7/74 reads (9%) | catalogued as COSV99491913; called by muse, mutect2
- ASAH2 | c.225C>A p.A75= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as COSV100269969; called by muse, mutect2
- ASXL1 | c.1818G>T p.R606= | Silent (SNP) | VAF 6/84 reads (7%) | catalogued as COSV100039615; called by muse, mutect2
- ASXL2 | c.3114C>G p.L1038= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV99711292; called by muse, mutect2, varscan2
- ASXL2 | c.2979C>T p.L993= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV99711295; called by muse, mutect2
- CCDC151 | c.1449C>T p.F483= | Silent (SNP) | VAF 27/75 reads (36%) | catalogued as rs367797540; called by muse, mutect2, varscan2
- CCDC66 | c.615A>G p.K205= (on ENST00000394672 / NM_001353147.1; = p.K171= on NM_001012506.5 and 6 other RefSeq transcripts) | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as rs1250823666, COSV100414046; called by muse, mutect2, varscan2
- CCDC93 | c.1158G>C p.L386= | Silent (SNP) | VAF 14/119 reads (12%) | catalogued as COSV100098940; called by muse, mutect2, varscan2
- CLCNKA | c.1014C>T p.I338= | Silent (SNP) | VAF 31/285 reads (11%) | catalogued as rs148622623, COSV100510142; called by muse, mutect2, varscan2
- CLPS | c.338G>A p.*113= | Silent (SNP) | VAF 10/100 reads (10%) | catalogued as COSV99463606, COSV99463707; called by muse, mutect2
- CNTNAP1 | c.3627C>T p.C1209= | Silent (SNP) | VAF 9/93 reads (10%) | catalogued as rs780384214, COSV99226553; called by muse, mutect2, varscan2
- CNTRL | c.4755G>C p.L1585= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV99442672; called by muse, mutect2, varscan2
- COQ5 | c.762C>T p.L254= | Silent (SNP) | VAF 5/76 reads (7%) | catalogued as rs1250176159, COSV56020236, COSV99942333; called by muse, mutect2
- CR2 | c.2895G>C p.L965= | Silent (SNP) | VAF 24/43 reads (56%) | catalogued as COSV100889659; called by muse, mutect2, varscan2
- CRB1 | c.3222G>A p.L1074= | Silent (SNP) | VAF 5/93 reads (5%) | catalogued as COSV66332570; called by muse, mutect2
- CRHR2 | c.537C>T p.S179= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as COSV100530048; called by muse, mutect2, varscan2
- CTNND2 | c.561G>A p.Q187= | Silent (SNP) | VAF 44/217 reads (20%) | catalogued as rs763613911, COSV58871634; called by muse, mutect2, varscan2
- DCLRE1B | c.831C>T p.S277= | Silent (SNP) | VAF 15/106 reads (14%) | catalogued as COSV100849797, COSV65812278; called by muse, mutect2, varscan2
- DDX56 | c.531A>G p.E177= | Silent (SNP) | VAF 22/135 reads (16%) | catalogued as COSV99346118; called by muse, varscan2
- DDX59 | c.639C>G p.V213= | Silent (SNP) | VAF 46/150 reads (31%) | catalogued as COSV100494572; called by muse, mutect2, varscan2
- DNAH5 | c.2913G>C p.L971= | Silent (SNP) | VAF 18/188 reads (10%) | catalogued as COSV99450537; called by muse, varscan2
- DOLK | c.210C>G p.V70= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as rs750368652, COSV65364214; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- EBF3 | c.243G>A p.P81= | Silent (SNP) | VAF 26/109 reads (24%) | catalogued as rs1281223839, COSV62474931; called by muse, mutect2, varscan2
- EEF1AKNMT | c.1152G>T p.R384= (on ENST00000361735 / NM_015935.5; = p.R298= on NM_014955.3) | Silent (SNP) | VAF 7/78 reads (9%) | catalogued as COSV100675889; called by muse, mutect2
- EIF2AK3 | c.1050C>G p.V350= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV100303799; called by muse, mutect2, varscan2
- EPHA1 | c.1458G>C p.L486= | Silent (SNP) | VAF 18/105 reads (17%) | catalogued as COSV99314112; called by muse, mutect2, varscan2
- FAM90A1 | c.273G>A p.A91= | Silent (SNP) | VAF 8/144 reads (6%) | catalogued as rs1433596194, COSV100274345; called by muse, mutect2
- FANCL | c.63G>C p.S21= | Silent (SNP) | VAF 12/90 reads (13%) | catalogued as COSV52078115, COSV99287650; called by muse, mutect2, varscan2
- FEZ1 | c.27T>C p.D9= | Silent (SNP) | VAF 17/93 reads (18%) | catalogued as COSV99630735; called by muse, mutect2, varscan2
- FGFR1 | c.1086G>C p.L362= (on ENST00000447712 / NM_023110.3; = p.L360= on NM_015850.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as COSV100248463; called by muse, mutect2
- FOXB1 | c.306C>T p.F102= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as COSV101249829, COSV68525674; called by muse, mutect2, varscan2
- FUT9 | c.324C>A p.I108= | Silent (SNP) | VAF 9/80 reads (11%) | catalogued as COSV100133758; called by muse, mutect2, varscan2
- GARNL3 | c.1062C>G p.L354= | Silent (SNP) | VAF 14/111 reads (13%) | catalogued as rs1227974245, COSV100150360; called by muse, mutect2, varscan2
- GK | c.447C>T p.F149= | Silent (SNP) | VAF 18/118 reads (15%) | catalogued as COSV100970879; called by muse, mutect2, varscan2
- GLB1 | c.360G>A p.L120= | Silent (SNP) | VAF 20/115 reads (17%) | catalogued as COSV56565809; called by muse, mutect2, varscan2
- GNLY | c.330C>T p.F110= | Silent (SNP) | VAF 18/76 reads (24%) | catalogued as COSV55704337; called by muse, mutect2, varscan2
- H4C11 | c.311G>A p.*104= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as rs113345516, COSV61827522; called by mutect2, varscan2
- HEATR1 | c.1062G>C p.L354= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV100857662; called by muse, mutect2, varscan2
- IGFBPL1 | c.618G>A p.G206= | Silent (SNP) | VAF 11/77 reads (14%) | catalogued as rs749624766, COSV66618371; called by muse, mutect2, varscan2
- IL17RE | c.1221C>G p.V407= | Silent (SNP) | VAF 25/168 reads (15%) | catalogued as COSV99925059; called by muse, mutect2, varscan2
- INPP5B | c.2790C>G p.V930= (on ENST00000373023; = p.V850= on NM_005540.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as COSV100886516; called by muse, mutect2, varscan2
- ITGA1 | c.2454C>T p.L818= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as COSV99251532; called by muse, mutect2, varscan2
- KCTD6 | c.384G>A p.K128= | Silent (SNP) | VAF 20/95 reads (21%) | catalogued as COSV100250192; called by muse, mutect2, varscan2
- KIAA1958 | c.1272G>C p.T424= | Silent (SNP) | VAF 6/68 reads (9%) | catalogued as COSV100516155; called by muse, mutect2, varscan2
- L3MBTL3 | c.1788T>C p.F596= | Silent (SNP) | VAF 24/146 reads (16%) | catalogued as COSV100696200; called by muse, mutect2, varscan2
- LCP1 | c.1770C>T p.A590= | Silent (SNP) | VAF 39/175 reads (22%) | catalogued as COSV100549929; called by muse, mutect2, varscan2
- LRRC55 | c.216G>T p.L72= | Silent (SNP) | VAF 16/90 reads (18%) | catalogued as COSV101546748; called by muse, mutect2
- MACF1 | c.6718C>T p.L2240= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as COSV99244914; called by muse, mutect2, varscan2
- MAOB | c.195G>A p.Q65= | Silent (SNP) | VAF 29/151 reads (19%) | catalogued as COSV100956088; called by muse, mutect2, varscan2
- MAST1 | c.282C>T p.L94= | Silent (SNP) | VAF 11/86 reads (13%) | catalogued as rs983340346, COSV99263081; called by muse, mutect2, varscan2
- MED25 | c.1344G>C p.L448= | Silent (SNP) | VAF 16/106 reads (15%) | catalogued as COSV100457496; called by muse, mutect2, varscan2
- MFHAS1 | c.2523G>A p.L841= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as COSV99359634; called by muse, mutect2, varscan2
- MON2 | c.1989A>T p.A663= | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as COSV99742776; called by muse, mutect2, varscan2
- MUC5B | c.7479C>T p.T2493= | Silent (SNP) | VAF 11/184 reads (6%) | catalogued as rs1325584031; called by muse, varscan2
- MYH15 | c.2508G>C p.V836= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as COSV99843424; called by muse, mutect2, varscan2
- MYO5B | c.729C>G p.L243= | Silent (SNP) | VAF 44/248 reads (18%) | catalogued as COSV99545264; called by muse, mutect2, varscan2
- MYRF | c.765G>A p.K255= (on ENST00000278836 / NM_001127392.3; = p.K246= on NM_013279.4) | Silent (SNP) | VAF 14/145 reads (10%) | catalogued as rs750977779, COSV99607226; called by muse, mutect2, varscan2
- NAXD | c.867C>G p.L289= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as COSV99959697; called by muse, mutect2, varscan2
- NCBP2 | c.318G>C p.L106= | Silent (SNP) | VAF 17/114 reads (15%) | catalogued as COSV100052069; called by muse, mutect2, varscan2
- NIPBL | c.7107G>A p.Q2369= | Silent (SNP) | VAF 17/90 reads (19%) | catalogued as COSV99240923; called by muse, mutect2, varscan2
- NPHP1 | c.1272C>G p.V424= (on ENST00000393272 / NM_207181.4; = p.V425= on NM_000272.5) | Silent (SNP) | VAF 18/101 reads (18%) | catalogued as COSV100338175; called by muse, mutect2, varscan2
- NPY2R | c.828G>C p.V276= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as COSV100279747; called by muse, mutect2, varscan2
- OR13D1 | c.186C>G p.L62= | Silent (SNP) | VAF 21/80 reads (26%) | catalogued as COSV100598696; called by muse, mutect2, varscan2
- OR2T11 | c.393C>G p.V131= | Silent (SNP) | VAF 24/84 reads (29%) | catalogued as COSV100424851; called by muse, mutect2, varscan2
- OR51F2 | c.120C>T p.A40= | Silent (SNP) | VAF 38/236 reads (16%) | catalogued as rs747026783, COSV59065505; called by muse, mutect2, varscan2
- OR8H3 | c.675C>T p.I225= | Silent (SNP) | VAF 11/155 reads (7%) | catalogued as COSV57912241; called by muse, mutect2
- OR8J3 | c.114C>T p.T38= | Silent (SNP) | VAF 18/139 reads (13%) | catalogued as COSV100040753, COSV100040778; called by muse, mutect2, varscan2
- OTUD7A | c.834G>A p.L278= (on ENST00000307050 / NM_001382637.1; = p.L271= on NM_130901.3) | Silent (SNP) | VAF 6/67 reads (9%) | catalogued as COSV100192614; called by muse, mutect2
- P2RY1 | c.645C>T p.F215= | Silent (SNP) | VAF 21/206 reads (10%) | catalogued as rs1399193902, COSV59310516; called by muse, mutect2, varscan2
- PCDHA1 | c.63C>T p.L21= | Silent (SNP) | VAF 10/83 reads (12%) | catalogued as COSV65377305; called by muse, mutect2, varscan2
- PCDHA2 | c.2139C>G p.L713= | Silent (SNP) | VAF 30/197 reads (15%) | catalogued as COSV100973917, COSV65369328; called by muse, mutect2, varscan2
- PCDHB15 | c.1458C>T p.V486= | Silent (SNP) | VAF 33/202 reads (16%) | catalogued as rs782114318, COSV99178978; called by muse, mutect2, varscan2
- PCDHGB3 | c.1851C>T p.F617= | Silent (SNP) | VAF 34/116 reads (29%) | catalogued as COSV99539836; called by muse, mutect2, varscan2
- PDZD7 | c.135G>A p.R45= | Silent (SNP) | VAF 17/122 reads (14%) | catalogued as COSV99827502; called by muse, mutect2, varscan2
- PLA2G5 | c.354C>G p.L118= | Silent (SNP) | VAF 11/89 reads (12%) | catalogued as COSV100908247; called by muse, mutect2, varscan2
- PML | c.2271C>G p.L757= | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as COSV99167345; called by muse, mutect2, varscan2
- PRKCE | c.1758C>T p.P586= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as COSV100078252; called by muse, mutect2, varscan2
- PRKCG | c.1749G>T p.V583= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as COSV99669144; called by muse, mutect2, varscan2
- PRPS1 | c.762C>T p.S254= | Silent (SNP) | VAF 17/161 reads (11%) | catalogued as rs780750403, COSV65054362; called by muse, mutect2, varscan2
- PRTG | c.723A>G p.P241= | Silent (SNP) | VAF 36/247 reads (15%) | catalogued as COSV101221403; called by muse, mutect2, varscan2
- PTPRA | c.216A>G p.G72= | Silent (SNP) | VAF 26/113 reads (23%) | catalogued as COSV99399961; called by muse, mutect2, varscan2
- RACK1 | c.327G>A p.L109= | Silent (SNP) | VAF 16/66 reads (24%) | catalogued as COSV65174728, COSV65175401; called by muse, mutect2, varscan2
- RSPH10B2 | c.1548C>G p.L516= | Silent (SNP) | VAF 16/136 reads (12%) | catalogued as COSV51868678, COSV99786208; called by muse, mutect2, varscan2
- SAFB2 | c.81G>A p.T27= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV52650821, COSV99385796; called by muse, mutect2, varscan2
- SCN11A | c.2271C>T p.S757= | Silent (SNP) | VAF 13/85 reads (15%) | catalogued as COSV100181736; called by muse, mutect2, varscan2
- SECISBP2 | c.2067G>C p.L689= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV100368700; called by muse, mutect2
- SEZ6L2 | c.2481C>G p.L827= (on ENST00000308713 / NM_001114099.3; = p.L757= on NM_012410.4) | Silent (SNP) | VAF 11/61 reads (18%) | catalogued as COSV100435508; called by muse, mutect2, varscan2
- SIPA1L2 | c.3330C>T p.D1110= | Silent (SNP) | VAF 20/85 reads (24%) | catalogued as COSV99478599; called by muse, mutect2, varscan2
- SLC12A4 | c.1392C>G p.L464= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as COSV100311846; called by muse, mutect2, varscan2
- SMO | c.1692G>A p.K564= | Silent (SNP) | VAF 24/112 reads (21%) | catalogued as COSV50825918; called by muse, mutect2, varscan2
- SPATA16 | c.1377G>A p.L459= | Silent (SNP) | VAF 46/431 reads (11%) | catalogued as COSV100651325; called by muse, mutect2, varscan2
- SPG11 | c.2418A>G p.E806= | Silent (SNP) | VAF 13/75 reads (17%) | catalogued as COSV99968841; called by muse, mutect2, varscan2
- SPNS2 | c.492C>A p.R164= | Silent (SNP) | VAF 26/125 reads (21%) | catalogued as COSV100223681; called by muse, mutect2, varscan2
- STN1 | c.45C>G p.L15= | Silent (SNP) | VAF 32/111 reads (29%) | catalogued as COSV99830240; called by muse, mutect2, varscan2
- TARBP1 | c.3363C>G p.V1121= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV99241744; called by muse, mutect2, varscan2
- TGIF2LX | c.177C>A p.A59= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as rs1569307838, COSV99383299, COSV99383406; called by mutect2, varscan2
- TMEM132A | c.222G>C p.L74= | Silent (SNP) | VAF 15/111 reads (14%) | catalogued as COSV99135378; called by muse, mutect2, varscan2
- TMEM18 | c.297C>T p.A99= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as COSV99806191; called by muse, mutect2, varscan2
- TRIM55 | c.1578C>G p.G526= | Silent (SNP) | VAF 27/218 reads (12%) | catalogued as COSV99396225; called by muse, mutect2, varscan2
- TTC19 | c.405C>T p.I135= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as COSV55422559; called by muse, mutect2, varscan2
- XPO1 | c.3168C>T p.V1056= | Silent (SNP) | VAF 13/81 reads (16%) | catalogued as rs556422732, COSV101294232; called by muse, mutect2, varscan2
- ZIC4 | c.468G>C p.T156= | Silent (SNP) | VAF 32/208 reads (15%) | catalogued as rs376509983, COSV101268009; called by muse, mutect2, varscan2
- ZMAT4 | c.393T>A p.A131= | Silent (SNP) | VAF 47/378 reads (12%) | catalogued as COSV99910211; called by muse, mutect2, varscan2
- ZNF155 | c.1284T>C p.Y428= | Silent (SNP) | VAF 16/88 reads (18%) | catalogued as rs1351717494, COSV99525719; called by muse, mutect2, varscan2
- ZNF320 | c.1098C>T p.F366= | Silent (SNP) | VAF 32/183 reads (17%) | catalogued as rs1289796293, COSV101206871; called by muse, mutect2, varscan2
- ZNF555 | c.456C>T p.F152= | Silent (SNP) | VAF 19/114 reads (17%) | catalogued as COSV100514667; called by muse, mutect2, varscan2
- CLN5 | chr13:76992037 G>A | 5'Flank (SNP) | VAF 6/13 reads (46%) | catalogued as COSV101080328; called by muse, mutect2, varscan2
- FGFR1 | c.937-1098G>C | Intron (SNP) | VAF 9/54 reads (17%) | catalogued as COSV100248469; called by muse, mutect2, varscan2
- IGKV1OR22-5 | n.198C>G | RNA (SNP) | VAF 14/107 reads (13%) | called by muse, mutect2, varscan2
- MIR15A | n.16G>C | RNA (SNP) | VAF 6/14 reads (43%) | called by muse, mutect2, varscan2
- MIR888 | n.63G>A | RNA (SNP) | VAF 5/29 reads (17%) | called by muse, mutect2, varscan2
- MIR888 | n.62G>T | RNA (SNP) | VAF 5/28 reads (18%) | called by muse, mutect2, varscan2
- OBSCN | c.11659+3571G>A | Intron (SNP) | VAF 30/157 reads (19%) | catalogued as rs745653420, COSV99479750; called by muse, mutect2, varscan2
- SLC7A2 | c.-2G>C | 5'UTR (SNP) | VAF 5/62 reads (8%) | catalogued as COSV99135112; called by muse, mutect2
- XIRP2 | c.-45G>C | 5'UTR (SNP) | VAF 5/45 reads (11%) | catalogued as COSV99743676; called by muse, mutect2, varscan2
